Surgical pathology report (de-identified scan), TCGA case TCGA-MJ-A68J, project TCGA-SARC (Sarcoma), tissue source site BLN - Baylor, specimen TCGA-MJ-A68J-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

ICD-0-3

Fibromyxosarcoma 8811/3

*Site: Connective, subcutaneous
and other soft tissues of leg
C49.2*

ADDENDUM

Addendum Comment

This addendum is issued to indicate the specific margins that are positive.

The following margins are positive: superomedial peripheral margin (inked blue), inferomedial peripheral margin (inked black) and the deep margin (multifocally in the superior, inferior, medial and lateral portions of the specimen, inked yellow and green).

9/20 5/21/13

End of Addendum Report or Additional Results

Staff Pathologist

PATHOLOGIC DIAGNOSIS

RIGHT PRETIBIAL MASS, SKIN AND SOFT TISSUE:

- MYXOID SARCOMA

- THIS LESION HAS FEATURES OF MYXOFIBROSARCOMA AS WELL AS ACRAL MYXOINFLAMMATORY FIBROBLASTIC SARCOMA. THE LESION IS PRESENT AT INKED TISSUE EDGES. COMPLETE EXCISION OF THIS LESION IS RECOMMENDED.

Staff Pathologist

Pertinent Clinical Information

year-old African American female with history of hypertension.

Gross Description

Specimen Material: Right pretibial mass, long lateral stitch, short superior stitch.

[page 2 of 2]
The specimen is received fresh labeled "RIGHT PRETIBIAL MASS, LONG LATERAL STITCH, SHORT SUPERIOR STITCH" and consists of a 6 x 5.5 x 1.2 cm tan-brown irregular skin excision excised to a depth of 0.7 cm, with a long stitch designating lateral and a short stitch designating superior. The superior margin is inked blue, the inferior margin is inked black. The superior deep margin is inked yellow and the inferior deep margin is inked green. The specimen is serially sectioned from medial to lateral yielding 11 slices approximately 0.4 cm thick. The cut section reveals a 5 x 5.1 x 0.7 cm tan-yellow multilobulated (possibly multi nodular), indurated diffuse mass with fibrous septae with mucoid surface abutting the deep margin. The mass is 0.5 cm from the medial margin and 0.4 cm from the lateral margin. The entire specimen is submitted as follows:

- 1: medial tip
- 2: slice 2
- 3: slice 3
- 4: slice 4
- 5: two pieces of slice 5
- 6-7: slice 6 (superior portion in 6, inferior portion in 7)
- 8-9: slice 7 (superior portion in 8, inferior portion in 9)
- 10-12: slice 8 (superior portion in 10, bulging slice of superior portion in 11, two pieces in 12-anterior portion and one piece is the bulging portion of margin without margins)
- 13-14: slice 9 (superior portion in 13, inferior portion in 14)
- 15: slice 10
- 16: slice 11, lateral tip

Pathology Resident

Microscopic Description

Sections reveal a neoplasm composed of spindle cells, some that are quite atypical with intranuclear inclusions. Many areas are quite myxoid. There are inflammatory cells present including lymphocytes, histiocytes, and eosinophils. The lesion is present at inked tissue edges. This case has also been reviewed at the dermatopathology consensus conference.

This case was reviewed by the staff pathologist listed below.

****Electronically Signed Out****

Staff Pathologist

erian	122	5/5/13	Yes	No
ing Discrepancy				✓
ary Tumor Site Discrepancy				✓
LA Discrepancy				✓
r Malignancy History				✓
/Synchronous Primary				
ower Initials	8-1	Date Reviewed	4/24/13	

Source: NCI Genomic Data Commons file 0b5a2368-b638-4ef8-9389-3f88269015cf (TCGA-MJ-A68J.A235D9F9-B61C-48E7-9022-9472F66F13D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).